Somatic mutation profile of tumor specimen TCGA-B5-A1N2-01A (aliquot TCGA-B5-A1N2-01A-21D-A142-09) from TCGA case TCGA-B5-A1N2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 70.1 years (25,612 days).
Specimen TCGA-B5-A1N2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ac58501-4670-49ff-ae24-aa822d4654a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1N2-10A (Blood Derived Normal), aliquot TCGA-B5-A1N2-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/349bc7c2-9d45-4717-85c6-027b02b9f416

The open-access MAF lists 146 somatic variants for this specimen: 120 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 23, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, RNA 2, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 42/72 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 49/62 reads (79%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACRV1 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100223634; called by muse, mutect2, varscan2
- ADGRB3 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV99486911; called by muse, mutect2, varscan2
- ADGRG2 | c.2048C>T p.S683L (on ENST00000379869 / NM_001079858.3; = p.S680L on NM_005756.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs376971597, COSV61341191; called by muse, mutect2, varscan2
- ADGRL1 | c.1793C>T p.S598L (on ENST00000340736 / NM_001008701.3; = p.S593L on NM_014921.5) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100529823; called by muse, mutect2
- AGAP6 | c.726G>C p.E242D (on ENST00000374056 / NM_001365867.1; = p.E265D on NM_001077665.2) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100929163; called by muse, mutect2, varscan2
- ATAD5 | c.2077-1G>T p.X693_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100430232; called by muse, mutect2, varscan2
- ATP13A5 | c.2205G>T p.M735I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100665739; called by muse, mutect2, varscan2
- ATP1A3 | c.2328del p.K777Sfs*7 (on ENST00000545399 / NM_001256214.2; = p.K764Sfs*7 on NM_152296.5) | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as COSV100132363; called by mutect2, pindel, varscan2
- BCOR | c.5019G>C p.L1673F (on ENST00000378444 / NM_001123385.2; = p.L1639F on NM_017745.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100654177; called by muse, mutect2, varscan2
- BNIPL | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99639978; called by muse, mutect2, varscan2
- CCDC88B | c.350C>G p.P117R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV100105954; called by muse, mutect2, varscan2
- CCT6B | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV100030506; called by muse, mutect2, varscan2
- CDK19 | c.1283A>C p.D428A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100099317; called by muse, mutect2, varscan2
- CDR2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as rs781572672, COSV99193574; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CHM | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100718399; called by muse, mutect2, varscan2
- CLPB | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99578701, COSV99578840; called by muse, mutect2
- CLPTM1 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.179); catalogued as rs1179033404, COSV100493963; called by muse, varscan2
- CLPTM1 | c.888G>C p.E296D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV100493967; called by muse, varscan2
- CNST | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780207242, COSV100829927, COSV63620926; called by muse, mutect2, varscan2
- CR1 | c.5179C>G p.L1727V | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.248); catalogued as COSV100888052; called by muse, mutect2
- CRTAC1 | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100086147, COSV54007566; called by muse, mutect2, varscan2
- CYP2W1 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100417330; called by muse, mutect2, varscan2
- DDC | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as CM166240, COSV100779762; called by muse, mutect2, varscan2
- DHX15 | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100391765; called by muse, mutect2, varscan2
- DHX36 | c.2081C>A p.A694E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273971; called by muse, mutect2, varscan2
- ELOVL2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as rs752445581, COSV61154717; called by muse, mutect2, varscan2
- EVPL | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101440977; called by muse, mutect2, varscan2
- EXOC2 | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100034245; called by muse, mutect2, varscan2
- FSTL5 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100061328; called by muse, mutect2
- GAS6 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100582275; called by muse, mutect2, varscan2
- GCC2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100565655; called by muse, mutect2
- GCG | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs767533221, COSV100972856; called by muse, mutect2, varscan2
- GDNF | c.433T>A p.C145S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100427571; called by muse, mutect2, varscan2
- GRPR | c.1042T>G p.S348A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100977704; called by muse, mutect2, varscan2
- GRPR | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100977705; called by muse, mutect2, varscan2
- H4C4 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as COSV100534364, COSV100534502; called by muse, mutect2
- HCAR2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs773465504, COSV61025251; called by muse, mutect2, varscan2
- HERC2 | c.3947A>G p.H1316R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV99876783; called by muse, mutect2, varscan2
- IK | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1302163722, COSV99347414; called by muse, mutect2, varscan2
- INCENP | c.2054C>T p.A685V (on ENST00000394818 / NM_001040694.2; = p.A681V on NM_020238.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99611584; called by muse, varscan2
- ITPR2 | c.4951G>A p.A1651T | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs753089598, COSV101190175; called by muse, mutect2, varscan2
- ITSN2 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100744198; called by muse, mutect2, varscan2
- KBTBD12 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV100675534; called by muse, mutect2, varscan2
- KDM5C | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100949487; called by muse, mutect2, varscan2
- KIF21A | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100735683; called by muse, mutect2, varscan2
- KNDC1 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100466280, COSV58848921; called by muse, mutect2, varscan2
- LILRA1 | c.1094C>A p.A365D | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV99252192; called by muse, mutect2
- LMAN2L | c.173C>G p.S58W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99383476, COSV99383641; called by muse, mutect2, varscan2
- LRIG2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100743719, COSV63162113; called by muse, mutect2, varscan2
- MAGEC3 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100026145; called by muse, mutect2
- ME1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100866702; called by muse, mutect2, varscan2
- MED23 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.39); catalogued as COSV100644882; called by muse, mutect2, varscan2
- MPDZ | c.2795A>G p.N932S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100057641; called by muse, mutect2, varscan2
- MYO18B | c.401G>C p.S134T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV100125240; called by muse, mutect2, varscan2
- MYO3A | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781651; called by muse, mutect2, varscan2
- NCKAP5 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100494460; called by muse, mutect2, varscan2
- NEBL | c.1433C>G p.A478G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV101009362; called by muse, mutect2, varscan2
- PDCD6IP | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.931); catalogued as COSV100219177; called by muse, mutect2, varscan2
- PLD1 | c.1895C>G p.T632R | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as COSV100578927; called by muse, mutect2, varscan2
- PLXNB3 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737947; called by muse, mutect2, varscan2
- PLXNC1 | c.2405T>G p.V802G | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV99313865; called by muse, mutect2
- POSTN | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs775213102, COSV65712393; called by muse, mutect2, varscan2
- PPFIA2 | c.2447G>A p.S816N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100335334; called by muse, mutect2, varscan2
- PPOX | c.617-1G>T p.X206_splice | Splice Site (SNP) | VAF 3/25 reads (12%) | catalogued as CS992472, COSV99237814; called by muse, mutect2
- PPP6C | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV101001255; called by muse, mutect2, varscan2
- PPRC1 | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs745337054, COSV99532112; called by muse, mutect2, varscan2
- PRB4 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 91/180 reads (51%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.839); catalogued as rs1247791441, COSV99686824; called by muse, mutect2, varscan2
- PRDM1 | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV100959009; called by muse, mutect2, varscan2
- QRICH2 | c.2515C>G p.R839G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV99428745, COSV99429225, COSV99429723; called by muse, mutect2, varscan2
- RAB3GAP2 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs1238170162, COSV52966961, COSV99425038; called by muse, mutect2, varscan2
- RADX | c.2367G>A p.M789I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV100998922; called by muse, mutect2, varscan2
- RALA | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99143483; called by muse, mutect2, varscan2
- RBBP4 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100995792; called by muse, mutect2, varscan2
- REV1 | c.3172A>G p.K1058E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1428235840, COSV99178871; called by muse, mutect2, varscan2
- REXO5 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV99759506; called by muse, mutect2, varscan2
- RMDN1 | c.865T>A p.Y289N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV101288482; called by muse, mutect2, varscan2
- RTL9 | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV101511802; called by muse, mutect2, varscan2
- RTN4 | c.1654C>A p.P552T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100463995; called by muse, mutect2, varscan2
- SACS | c.5366C>A p.P1789Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV101207739; called by muse, mutect2
- SAMD3 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV100932099; called by muse, mutect2, varscan2
- SKOR1 | c.2517C>G p.G839= | Splice Region (SNP) | VAF 22/58 reads (38%) | catalogued as COSV100408634, COSV58246558; called by muse, mutect2, varscan2
- SLC36A4 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100419481, COSV58397229; called by muse, mutect2
- SLC4A4 | c.911G>C p.R304T (on ENST00000264485 / NM_001098484.3; = p.R260T on NM_003759.4) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99142486; called by muse, mutect2, varscan2
- SLC5A9 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99362016; called by muse, mutect2, varscan2
- SLC6A9 | c.973G>C p.V325L (on ENST00000360584 / NM_201649.4; = p.V271L on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.892); catalogued as COSV100746527, COSV100746583; called by muse, mutect2, varscan2
- SLITRK5 | c.2603C>T p.T868I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs766698379, COSV100281221; called by muse, mutect2, varscan2
- SMG1 | c.9893A>C p.Q3298P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV101246866; called by muse, mutect2, varscan2
- SOCS5 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs1464246989, COSV100125498, COSV60605700; called by muse, mutect2, varscan2
- SRFBP1 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as rs757055759, COSV59584724; called by muse, mutect2, varscan2
- STIL | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99681357; called by muse, mutect2, varscan2
- STK4 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860480; called by muse, mutect2, varscan2
- TANC2 | c.3271G>C p.A1091P | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV101267681; called by muse, mutect2, varscan2
- TBX5 | c.879T>G p.C293W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100092200; called by muse, mutect2, varscan2
- TEX35 | c.460T>A p.C154S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99275019; called by muse, mutect2, varscan2
- TMEM47 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99327949; called by muse, mutect2, varscan2
- TMEM94 | c.1465T>C p.W489R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.216); catalogued as COSV100050962; called by muse, mutect2, varscan2
- TMPRSS13 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); catalogued as rs772770055, COSV101471502, COSV101471511; called by muse, mutect2, varscan2
- TPO | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100222204; called by muse, mutect2, varscan2
- TREML2 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101530193; called by muse, mutect2, varscan2
- TREML2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV101530194, COSV72439024; called by muse, mutect2, varscan2
- TRIM38 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV100837649; called by muse, mutect2, varscan2
- UBAP2L | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV99672339; called by muse, mutect2, varscan2
- UBP1 | c.1067C>G p.A356G | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99372920; called by muse, mutect2, varscan2
- UNC13C | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV52851549; called by muse, mutect2, varscan2
- URB2 | c.2195G>T p.G732V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99032886, COSV99271932; called by muse, mutect2, varscan2
- ZFP82 | c.1136A>G p.Y379C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101089332; called by muse, mutect2
- ZFPM2 | c.2849A>T p.Q950L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101023575; called by muse, mutect2, varscan2
- ZNF383 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV61938563; called by muse, mutect2, varscan2
- ZNF528 | c.1000T>C p.F334L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100846762; called by muse, mutect2, varscan2
- ZNF560 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1418396470, COSV100039044; called by muse, mutect2, varscan2
- ZNF804B | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV100306293, COSV60856524; called by muse, mutect2, varscan2
- ZNF831 | c.4154G>C p.R1385T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV100926082, COSV100926273; called by muse, mutect2
- AFTPH | c.1741del p.D581Ifs*69 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- CEP290 | c.927del p.V310* | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- IFI44L | c.165_193del p.I56Afs*6 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- SLC6A13 | c.362T>A p.I121N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SP2 | c.489_524del p.N163_H174del | In Frame Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel
- BCO1 | c.1134G>T p.V378= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99258692; called by muse, mutect2
- BCORL1 | c.1050T>A p.P350= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- C6 | c.1554C>T p.F518= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs761609979, COSV54706119; called by muse, mutect2, varscan2
- CCDC105 | c.1158C>T p.H386= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99480140; called by muse, mutect2
- COL27A1 | c.105C>T p.H35= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV100621341; called by muse, mutect2, varscan2
- DCHS1 | c.4908C>G p.T1636= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100202616; called by muse, mutect2, varscan2
- DHCR24 | c.1095C>G p.L365= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100987847; called by muse, mutect2, varscan2
- ENTHD1 | c.786C>T p.I262= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100289146; called by muse, mutect2, varscan2
- GIPC1 | c.915C>T p.D305= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs767735611, COSV99466663; called by muse, mutect2
- GRIP1 | c.2481C>G p.A827= (on ENST00000359742 / NM_001379345.1; = p.A775= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99671068; called by muse, mutect2, varscan2
- HEPH | c.1815A>T p.R605= (on ENST00000343002; = p.R338= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100295757; called by muse, mutect2, varscan2
- HK2 | c.711C>T p.C237= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99309586; called by muse, mutect2, varscan2
- INSIG2 | c.677G>A p.*226= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV55523105; called by muse, mutect2, varscan2
- JUP | c.1632A>T p.A544= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100159813; called by muse, mutect2
- LCA5 | c.1086A>T p.G362= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100878369; called by muse, mutect2, varscan2
- MAP3K15 | c.1983C>G p.G661= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100135760; called by muse, mutect2, varscan2
- MYOM1 | c.4827C>T p.N1609= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs745895344, COSV55292030, COSV99868421; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPHP3 | c.3951A>T p.T1317= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99393410; called by muse, mutect2
- RANBP6 | c.300A>G p.E100= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99424434; called by muse, mutect2, varscan2
- SIK2 | c.846C>A p.L282= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV100516496; called by muse, mutect2, varscan2
- SRGAP3 | c.2007G>T p.G669= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100841455, COSV64530750; called by muse, mutect2, varscan2
- TNXB | c.9420C>T p.H3140= (on ENST00000647633; = p.H2893= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1478716332, COSV100926665; called by muse, mutect2, varscan2
- YIPF2 | c.117C>T p.H39= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs549120826, COSV53403121, COSV99450343; called by muse, mutect2
- MIR646 | n.6G>A | RNA (SNP) | VAF 8/14 reads (57%) | catalogued as rs747719425; called by muse, mutect2
- PARP15 | c.772-23T>A | Intron (SNP) | VAF 26/140 reads (19%) | catalogued as COSV100117228; called by muse, mutect2, varscan2
- ZNF767P | n.531G>C | RNA (SNP) | VAF 26/68 reads (38%) | catalogued as rs1302060412; called by muse, mutect2, varscan2
